Somatic mutation profile of tumor specimen BA3246D (aliquot aq-BA3246D) from BEATAML1.0 case 2732, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,506 days).
Specimen BA3246D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced2e50e-7f6b-478e-b463-7aed0048c89e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3425D (Solid Tissue Normal), aliquot aq-BA3425D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d089cdde-ff28-43d1-9f24-b7e0bd9a69d2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772888814, COSV60391197; called by muse, mutect2, varscan2
- MUC5B | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
